Gene-level copy-number profile of tumor specimen C3N-03021-01 from CPTAC case C3N-03021, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 50.6 years (18,491 days).
Specimen C3N-03021-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5c4dc2d2-0643-4ce0-9e0f-f2751e428d79.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03021-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/c3e2d03e-dd70-4c6d-9002-54ada5e4f9fd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,365; copy number 2: 50,767; copy number 3: 3,773; copy number 4: 3; copy number 5: 5; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:6,704,270–6,707,780, 1 gene, copy number 15: LINC02851.
- chr12:50,939,927–51,028,566, 5 genes, copy number 5 (within-gene range 3–5): Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2.

Autosomal genes at a single copy (total copy number 1): 1,509. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
